Gene-level copy-number profile of tumor specimen TCGA-L5-A8NE-01A from TCGA case TCGA-L5-A8NE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 77.3 years (28,243 days).
Specimen TCGA-L5-A8NE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.4adc68db-fab2-448e-b7ab-1e4d298bdea3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NE-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/629a90ed-b00d-4bd1-9e2c-4e46386d6f82

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 472; copy number 2: 11,650; copy number 3: 16,471; copy number 4: 21,329; copy number 5: 3,361; copy number 6: 4,612; copy number 7: 729; copy number 8: 243; copy number 9: 294; copy number 10: 344; copy number 11: 115; copy number 12: 31; copy number 13: 65; copy number 14: 25; copy number 16: 14; copy number 22: 15; copy number 23: 2; copy number 30: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NE-01A-11D-A37B-01): tumor purity 0.64, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:75,430,571–75,431,588, 1 gene: AC010997.2.
- chr10:75,450,081–75,643,106, 4 genes: AC010997.6, MIR606, AL589863.2, AL589863.1.
- chr20:15,021,553–15,022,958, 2 genes: RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 934 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,425,257–11,880,406, 21 genes, copy number 12: MTCYBP45, DISP3, AL590989.1, LINC01647, AL031731.1, FBXO2, FBXO44, FBXO6, MAD2L2, DRAXIN, AGTRAP, C1orf167, C1orf167-AS1, MTHFR, CLCN6, AL021155.2, AL021155.3, NPPA, AL021155.1, NPPB, SBF1P2.
- chr1:22,364,630–22,921,500, 12 genes, copy number 9: AL591122.1, ZBTB40, ZBTB40-IT1, EPHA8, MIR6127, C1QA, C1QC, C1QB, EPHB2, MIR4684, AL512444.1, MIR4253.
- chr1:159,346,166–159,469,068, 1 gene, copy number 10 (within-gene range 5–10): AL513323.1.
- chr1:159,405,423–160,428,670, 53 genes, copy number 10 (within-gene range 5–10): OR10J9P, OR10J4, OR10J1, LINC02819, OR10J5, AL606752.1, OR10AE1P, APCS, OR10J6P, AL445528.2, CRPP1, CRP, AL445528.1, DUSP23, FCRL6, SLAMF8, AL590560.2, SNHG28, AL590560.1, VSIG8, AL590560.3, CFAP45, MIR4259, AL590560.5, AL590560.4, TAGLN2, IGSF9, SLAMF9, LINC01133, AL513485.1, KCNJ10, AL513302.1, PIGM, AL121987.1, KCNJ9, IGSF8, ATP1A2, ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2.
- chr1:160,995,211–161,714,352, 53 genes, copy number 9: F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2, AL831711.1, FCGR2A, AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1, FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1, RPL31P11, Y_RNA, FCRLA.
- chr1:213,051,233–214,041,510, 9 genes, copy number 10 (within-gene range 5–10): RPS6KC1, RPL31P13, AL592402.1, AC096639.1, PROX1-AS1, LINC00538, PROX1, AC011700.1, AL606537.1.
- chr1:234,527,887–234,970,062, 20 genes, copy number 13: LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2.
- chr3:155,024,124–156,540,627, 30 genes, copy number 10–13 (within-gene range 2–13): MME, MME-AS1, LINC01487, STRIT1, AC104831.1, PABPC1P10, PLCH1, AC108729.3, AC108729.2, AC108729.1, RN7SL715P, PLCH1-AS1, PLCH1-AS2, RPL6P7, AC104472.1, AC104472.2, C3orf33, AC104472.3, SLC33A1, AC104472.4, GMPS, AC104472.5, SETP14, VN2R1P, KCNAB1, ALG1L15P, MRE11P1, AC091607.2, AC091607.1, KCNAB1-AS2.
- chr3:170,222,424–170,860,380, 8 genes, copy number 10 (within-gene range 6–10): PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828.
- chr3:170,459,548–170,586,075, 2 genes, copy number 10: SLC7A14, KRT8P13.
- chr3:177,294,442–177,349,166, 3 genes, copy number 13: LINC00501, ASS1P7, AC117465.1.
- chr3:184,006,338–185,052,614, 43 genes, copy number 11 (within-gene range 5–11): ABCC5-AS1, EEF1A1P8, HTR3D, HTR3C, HTR3C2P, Y_RNA, HTR3E-AS1, HTR3E, HSP90AA5P, AC131235.3, AC131235.2, EIF2B5, AC131235.1, DVL3, AP2M1, ABCF3, VWA5B2, MIR1224, ALG3, EEF1AKMT4, EEF1AKMT4-ECE2, CAMK2N2, ECE2, PSMD2, EIF4G1, SNORD66, FAM131A, CLCN2, POLR2H, THPO, CHRD, LINC02054, AC128714.2, LINC01839, LINC01840, EPHB3, MAGEF1, AC107294.2, LINC02069, AC107294.3, AC107294.1, AC107294.4, VPS8.
- chr3:187,698,259–188,154,057, 11 genes, copy number 16: RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr3:188,178,543–188,180,812, 1 gene, copy number 16: FLJ42393.
- chr5:140,071,312–140,594,570, 24 genes, copy number 9: MALINC1, PURA, IGIP, AC011379.2, CYSTM1, AC011379.1, PFDN1, HBEGF, AC008438.2, SLC4A9, AC008438.1, RNU4-14P, ANKHD1, ANKHD1-EIF4EBP3, AC011399.1, SRA1, EIF4EBP3, APBB3, AC116353.5, MIR6831, SLC35A4, AC116353.6, AC116353.1, HAUS1P1.
- chr6:30,163,206–31,180,731, 71 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr6:36,027,677–36,639,672, 17 genes, copy number 10 (within-gene range 5–10): MAPK14, Z95152.1, MAPK13, Z84485.1, BRPF3, PNPLA1, BNIP5, ETV7, ETV7-AS1, PXT1, KCTD20, RN7SL502P, STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P.
- chr10:95,907,603–96,513,926, 13 genes, copy number 9 (within-gene range 3–9): CC2D2B, RPL21P90, CCNJ, MIR3157, RNU6-271P, AC021037.1, ZNF518A, BLNK, NPM1P25, AL136181.1, DNTT, OPALIN, TLL2.
- chr11:60,785,333–64,166,113, 180 genes, copy number 10 (broad region; genes not listed).
- chr11:74,397,549–74,949,200, 21 genes, copy number 9–14 (within-gene range 3–14): AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1, RNF169, XRRA1, AP000560.1, RN7SL239P.
- chr12:50,504,985–51,037,602, 19 genes, copy number 9: DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P.
- chr12:68,610,855–71,710,374, 68 genes, copy number 11–30 (broad region; genes not listed).
- chr12:77,219,603–77,317,234, 1 gene, copy number 16: LINC02464.
- chr12:77,379,770–77,390,869, 1 gene, copy number 16: AC073591.1.
- chr12:85,036,314–85,882,992, 7 genes, copy number 13 (within-gene range 2–13): LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS.
- chr12:85,958,686–86,016,441, 2 genes, copy number 13: AC016993.1, AC139697.1.
- chr14:75,127,153–75,298,109, 10 genes, copy number 12: AL049780.2, TMED10, AL691403.2, RNU4ATAC14P, AL691403.1, AF111167.1, U2, FOS, DPPA5P4, LINC01220.
- chr17:19,334,308–19,897,287, 40 genes, copy number 11: B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1, ULK2, NDUFB4P3, AC015726.3, AC015726.2, AC015726.1.
- chr17:19,929,372–19,929,737, 1 gene, copy number 11: AC005730.3.
- chr17:75,272,981–75,524,735, 13 genes, copy number 9: SLC25A19, GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54.
- chr18:20,946,906–22,348,252, 38 genes, copy number 10: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1.
- chr19:29,775,504–30,228,715, 14 genes, copy number 14: AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:30,850,975–32,072,113, 16 genes, copy number 11 (within-gene range 6–11): AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837.
- chr19:34,092,561–34,832,869, 29 genes, copy number 10 (within-gene range 4–10): RPS4XP21, CHCHD2P3, LSM14A, GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP, RPS26P55, ZNF807P, SCGB1B2P, SCGB2B2, AC020910.4, AC020910.1, AC020910.2, AC020910.7, SCGB2B3P, AC020910.6, ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801.
- chr19:38,867,830–40,226,697, 79 genes, copy number 9 (broad region; genes not listed).
- chr21:41,559,125–41,582,887, 3 genes, copy number 13: AP001610.3, AP006748.1, PCSEAT.

Autosomal genes at a single copy (total copy number 1): 472. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
